MMRF case MMRF_2119 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3f17e0fb-e10a-4061-8378-709a91a4cc13

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.0 years (22,268 days); ISS stage: III; Days to last known disease status: 891 days (2.4 years); Days to last follow up: 891 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 191 days; Days to treatment end: 442 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 422 days (1.2 years); Days to treatment end: 530 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 527 days (1.4 years); Days to treatment end: 654 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 653 days (1.8 years); Days to treatment end: 716 days (2.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 736 days (2.0 years); Days to treatment end: 785 days (2.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 771 days (2.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 240 mg/dL; Immunoglobulin G 5.41 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 7.5 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.75 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 6.82 mmol/L.
- Day 79 (ECOG 1): M Protein 0.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.17 mg/dL; Hemoglobin 7.19 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.65 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 5.83 mmol/L.
- Day 183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 5.5 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 48 ×10⁹/L; Absolute Neutrophil 42.7 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.94 mmol/L.
- Day 246 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Hemoglobin 9.24 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 407 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.45 mmol/L.
- Day 344 (ECOG 1): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.12 mg/dL; Immunoglobulin G 4.98 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 307 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 7.87 mmol/L.
- Day 442 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.35 mg/dL; Hemoglobin 7.81 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 331 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.
- Day 526: Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.4 mg/dL; Hemoglobin 7.19 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 4.51 mmol/L.
- Day 617: M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 101 mg/dL; Hemoglobin 7.19 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 5.17 mmol/L.
- Day 716 (ECOG 1): Hemoglobin 7.01 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 6.82 mmol/L.
- Day 794 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 593 mg/dL; Hemoglobin 6.26 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 166 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.65 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.89 mmol/L.
- Day 891 (ECOG 1): Hemoglobin 6.01 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 183 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 5.4 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -11: Weight: 82 kg; Height: 151 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2119_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_2119_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
